Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A3CE, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A3CE-06A (Metastatic).

1CD-0-3

Melanoma, NOS 8720/3

Path: Site: Chest wall, NOS C76.1

CQCF: lymph node, NOS C77.9

fw 10/3/11

DL
Pe

(A) SKIN AND SOFT TISSUE, RIGHT CHEST WALL:

METASTATIC MALIGNANT MELANOMA IN SOFT TISSUE (MULTIFOCAL) AND IN FOUR OF FIVE LYMPH NODES.

(B) SKIN AND SUBCUTANEOUS TISSUE, RIGHT SUPERIOR BREAST:

METASTATIC MALIGNANT MELANOMA IN SUBCUTANEOUS TISSUE.

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) WIDE LOCAL EXCISION MELANOMA OF THE SOFT TISSUE RIGHT CHEST WALL - An excision specimen of skin and underlying soft tissue (40.0 x 7.5 x 2.3 cm overall) including a portion of skeletal muscle (7.0 x 5.0 x 1.5 cm) and attached portion of tan skin (19.5 x 3.0 cm). Two subcutaneous nodules are identified. One nodule is located near the portion of skeletal muscle (2.5 x 1.7 x 1.6 cm) and is predominantly hemorrhagic and necrotic. An additional subcutaneous nodule is located under a portion of skin (2.3 x 2.0 x 1.8 cm). The tumor is tan and fleshy. An additional tumor nodule is present in the dermis and subcutaneous tissue adjacent to a portion of skin (3.0 x 1.7 x 1.7 cm). Multiple lymph nodes are identified within the soft tissue adjacent to the skeletal muscle. Lymph nodes range in greatest dimension from 0.3 up to 2.0 cm. Each of the nodules appear widely free of surgical margins. Portions of tumor are submitted for melanoma tumor bank.

SECTION CODE: A1, subcutaneous nodule near muscle; A2, subcutaneous nodule and skin; A3, dermal nodule with skin; A4, five lymph nodes; A5, two lymph nodes; A6-A7, one lymph node bisected; A8-A9, one lymph node bisected.

(B) RIGHT SUPERIOR BREAST LESION - A portion of skin (1.5 x 0.7 cm) with attached subcutaneous tissue (2.4 x 2.0 x 0.8 cm overall). Within the subcutaneous tissue is a tan-gray hemorrhagic circumscribed nodule (0.6 x 0.6 x 0.5 cm).

INK CODE: Blue = soft tissue margin.

SECTION CODE: B1, tips; B2, entire nodule.

CLINICAL HISTORY

Melanoma right upper abdominal wall.

SNOMED CODES

T-D3050, M-87206

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

. These tests have not been

Released by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 5c8800a7-4a8b-4af4-b0c2-a7f207087d40 (TCGA-D3-A3CE.913F7FE1-97D5-4729-B40F-9EC419903493.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).